Somatic mutation profile of tumor specimen MBCProject_3896_T2_WES (aliquot MBCProject_3896_T2_WES_1) from CMI case MBCProject_3896, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 70.2 years (25,655 days).
Specimen MBCProject_3896_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91f28967-d5d2-446b-9697-8042c426ef41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3896_SALIVA (Saliva), aliquot MBCProject_3896_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85c37d90-491f-43f2-8226-e8f4df05821b

The open-access MAF lists 214 somatic variants for this specimen: 133 protein-altering or splice-affecting, 52 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 52, Nonsense Mutation 12, Intron 12, 5'UTR 5, 3'UTR 4, Frame Shift Del 4, RNA 4, 5'Flank 2, Splice Site 2, 3'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ESR1 | c.1609T>A p.Y537N | Missense Mutation (SNP) | VAF 90/511 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52784978, COSV52804811, COSV99237981; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 13/85 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTSL3 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 49/269 reads (18%) | catalogued as COSV54446085, COSV99716519; called by muse, mutect2, varscan2
- ADH1A | c.887C>G p.P296R | Missense Mutation (SNP) | VAF 49/329 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV52924648; called by muse, mutect2, varscan2
- ANKRD45 | c.452C>A p.A151D | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100322686; called by muse, mutect2, varscan2
- BMP4 | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as rs1237655395; called by muse, mutect2, varscan2
- CCN3 | c.605C>G p.S202* | Nonsense Mutation (SNP) | VAF 30/626 reads (5%) | catalogued as rs796052179; ClinVar: likely benign; called by muse, mutect2
- CLEC9A | c.578C>G p.S193C | Missense Mutation (SNP) | VAF 74/311 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as rs997271993; called by muse, mutect2, varscan2
- CNOT6 | c.602A>G p.Y201C | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56163640; called by muse, mutect2, varscan2
- CYTL1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 108/655 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.36); catalogued as rs137887145, COSV57037313; called by muse, mutect2, varscan2
- DCHS1 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs374282596, COSV55040917; called by muse, mutect2, varscan2
- GALNT15 | c.1840G>T p.D614Y | Missense Mutation (SNP) | VAF 36/455 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100327802; called by muse, mutect2
- GLT6D1 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs756561670, COSV65627142; called by muse, mutect2, varscan2
- HEY1 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 44/751 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV61232637; called by muse, mutect2
- HSPA13 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 91/346 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV53465501; called by muse, mutect2, varscan2
- LRRC36 | c.940G>A p.G314S | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.979); catalogued as rs544699196; called by muse, mutect2, varscan2
- LRRC74A | c.558G>C p.E186D | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.07); catalogued as rs760611288; called by muse, mutect2, varscan2
- MKI67 | c.1729G>T p.V577F | Missense Mutation (SNP) | VAF 69/268 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV64077502; called by muse, mutect2, varscan2
- MUC5B | c.13419G>T p.Q4473H | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV101500297; called by muse, mutect2, varscan2
- MYO1D | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 35/254 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59024000; called by muse, mutect2, varscan2
- N4BP2L2 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 60/475 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57227461; called by muse, mutect2, varscan2
- NES | c.2661G>C p.E887D | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV104427526; called by muse, mutect2, varscan2
- OR1M1 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs1332959232, COSV101447568, COSV101447600; called by muse, mutect2, varscan2
- OR2T3 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.443); catalogued as COSV62082197; called by muse, mutect2
- OR4C6 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as COSV100051526, COSV100051727; called by muse, mutect2
- PALB2 | c.3404G>C p.G1135A | Missense Mutation (SNP) | VAF 26/334 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730881894; ClinVar: uncertain significance; called by muse, mutect2
- PHACTR3 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs960726257; called by muse, mutect2
- POF1B | c.370C>G p.P124A | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs757732492; called by muse, mutect2, varscan2
- PPIP5K2 | c.3649C>T p.P1217S (on ENST00000358359 / NM_001276277.3; = p.P1196S on NM_015216.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/226 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs782146288; called by muse, mutect2, varscan2
- PREX2 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 68/476 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55749568; called by muse, mutect2, varscan2
- PTAFR | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV59536724; called by muse, mutect2, varscan2
- RAD50 | c.1982G>C p.G661A | Missense Mutation (SNP) | VAF 44/388 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.93); catalogued as rs758063640; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAD51C | c.1040G>C p.R347T | Missense Mutation (SNP) | VAF 58/350 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100506977; called by muse, mutect2, varscan2
- SLFN12 | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as COSV59227284; called by mutect2, varscan2
- SRPK2 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 53/511 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs1340874246, COSV100624330, COSV61963906; called by muse, mutect2, varscan2
- SUPT6H | c.3540G>C p.Q1180H | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV100112207; called by muse, mutect2, varscan2
- TBC1D10A | c.903G>C p.K301N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs749396893; called by muse, mutect2, varscan2
- TBC1D2 | c.1309C>G p.P437A | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.027); catalogued as rs375721269; called by muse, mutect2, varscan2
- TMEM161B | c.547A>G p.M183V | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs369774401; called by muse, varscan2
- TP53BP1 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 44/197 reads (22%) | catalogued as COSV99781802; called by muse, mutect2, varscan2
- TRIM10 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 66/481 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs769419657, COSV100938926, COSV64989187; called by muse, mutect2, varscan2
- TTLL11 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs138558032; called by muse, mutect2, varscan2
- TTN | c.76948G>A p.E25650K (on ENST00000591111; = p.E18226K on NM_003319.4) | Missense Mutation (SNP) | VAF 44/342 reads (13%) | PolyPhen benign (0.254); catalogued as COSV60187286; called by muse, mutect2, varscan2
- UNKL | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 48/327 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.06); catalogued as rs574913319, COSV50190477, COSV99201402; called by muse, mutect2, varscan2
- USH2A | c.11488C>T p.L3830F | Missense Mutation (SNP) | VAF 50/413 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV100232460; called by muse, varscan2
- ZNF451 | c.1195T>A p.L399I | Missense Mutation (SNP) | VAF 54/354 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as COSV62597107, COSV62598161; called by muse, mutect2, varscan2
- ZNF830 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as rs1567676596; called by muse, mutect2, varscan2
- ABCF1 | c.1393G>A p.A465T (on ENST00000326195 / NM_001025091.2; = p.A427T on NM_001090.3) | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAM11 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ADAMTS5 | c.2289C>G p.F763L | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- ADGRE5 | c.1188_1200del p.A397Sfs*7 (on ENST00000242786 / NM_078481.4; = p.A304Sfs*7 on NM_001784.5) | Frame Shift Del (DEL) | VAF 16/87 reads (18%) | called by mutect2, pindel
- AP002495.1 | c.458C>G p.S153* (on ENST00000528511; = p.S84* on NM_001375848.1) | Nonsense Mutation (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
- ARHGEF10 | c.2349_2350del p.V784Sfs*3 (on ENST00000398564; = p.V759Sfs*3 on NM_014629.4) | Frame Shift Del (DEL) | VAF 49/238 reads (21%) | called by mutect2, pindel, varscan2
- ARL6 | c.371C>A p.P124Q | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARMC2 | c.2262G>C p.L754F | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATN1 | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.488); called by muse, mutect2
- BAALC | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 41/404 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- BATF | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 51/225 reads (23%) | called by muse, mutect2, varscan2
- BUB1B | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- C16orf86 | c.932dup p.L312Afs*21 | Frame Shift Ins (INS) | VAF 63/377 reads (17%) | called by mutect2, pindel, varscan2
- CAMK1G | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- CAMKMT | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- CEP83 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by mutect2, varscan2
- CMYA5 | c.8154G>C p.E2718D | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- CRYBG2 | c.3949C>T p.Q1317* | Nonsense Mutation (SNP) | VAF 43/227 reads (19%) | called by muse, mutect2, varscan2
- DAP | c.308G>T p.*103Lext*20 | Nonstop Mutation (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- DRD1 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- EGFLAM | c.177G>C p.R59S | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- EIF2AK2 | c.1540C>A p.L514I | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, varscan2
- EPM2A | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 54/290 reads (19%) | SIFT tolerated, low confidence (0.09); called by muse, mutect2, varscan2
- FAM111B | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- GARRE1 | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 47/1794 reads (3%) | called by muse, mutect2
- GCNT4 | c.190A>T p.K64* | Nonsense Mutation (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
- GDPD2 | c.117C>G p.I39M | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GGT5 | c.252G>C p.Q84H | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); called by muse, mutect2
- GRAMD1C | c.314C>G p.S105* | Nonsense Mutation (SNP) | VAF 16/98 reads (16%) | called by muse, varscan2
- GSDME | c.857A>C p.K286T | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.054); called by muse, mutect2
- GSTA4 | c.403G>T p.V135L | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- HDAC3 | c.655C>G p.L219V | Missense Mutation (SNP) | VAF 44/393 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HK3 | c.2470A>T p.M824L | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- HMCN1 | c.5011C>T p.P1671S | Missense Mutation (SNP) | VAF 33/372 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HOMER1 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HS6ST1 | c.746_793del p.R249_N264del | In Frame Del (DEL) | VAF 22/146 reads (15%) | called by mutect2, pindel
- IL19 | c.361T>C p.C121R | Missense Mutation (SNP) | VAF 60/430 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IQCB1 | c.592G>C p.D198H | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- IWS1 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 58/406 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JAKMIP2 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KLK4 | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 37/476 reads (8%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.99); called by muse, mutect2
- KMT2C | c.7238C>T p.A2413V | Missense Mutation (SNP) | VAF 83/546 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRT7 | c.46G>C p.A16P | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRP1 | c.2665C>G p.L889V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MSI2 | c.782G>C p.R261T | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.021); called by muse, mutect2
- MUC16 | c.22127G>T p.G7376V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- MYO18B | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- NARS2 | c.305C>A p.P102Q | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- NFXL1 | c.1268A>C p.E423A | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NOTCH2 | c.3824C>G p.S1275C | Missense Mutation (SNP) | VAF 21/723 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.319); called by muse, mutect2
- NUP107 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- NWD1 | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- OR5M3 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- OTOP2 | c.789G>T p.K263N | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PALM | c.675C>A p.H225Q | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PAX1 | c.765_786del p.Y256Rfs*64 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel
- PCM1 | c.2193-1G>C p.X731_splice | Splice Site (SNP) | VAF 18/168 reads (11%) | called by muse, mutect2, varscan2
- PIEZO2 | c.8C>A p.S3* | Nonsense Mutation (SNP) | VAF 36/119 reads (30%) | called by muse, mutect2, varscan2
- PLEKHG5 | c.2281G>T p.G761C (on ENST00000400915 / NM_001042663.3; = p.G724C on NM_020631.6) | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.319); called by mutect2, varscan2
- PRKDC | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 40/354 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PSKH1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- PSKH1 | c.685C>G p.P229A | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- QSOX1 | c.1657A>T p.R553W | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- RAD50 | c.1818G>C p.Q606H | Missense Mutation (SNP) | VAF 42/291 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- RAD50 | c.2205G>A p.M735I | Missense Mutation (SNP) | VAF 66/605 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, varscan2
- RBM19 | c.995A>C p.K332T | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- RXFP1 | c.1046G>T p.S349I | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- SCN3A | c.3184A>C p.N1062H | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIRT4 | c.413A>T p.Y138F | Missense Mutation (SNP) | VAF 93/413 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SMARCA2 | c.4570G>A p.D1524N | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SNX13 | c.1822T>A p.F608I | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); called by muse, varscan2
- SPINK5 | c.1961_1986del p.R654Qfs*7 | Frame Shift Del (DEL) | VAF 54/644 reads (8%) | called by mutect2, pindel
- SPINT2 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 92/1351 reads (7%) | called by muse, mutect2
- STAB2 | c.5198C>A p.P1733H | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TENM2 | c.2845G>C p.V949L (on ENST00000518659 / NM_001122679.2; = p.V717L on NM_001080428.3) | Missense Mutation (SNP) | VAF 79/278 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TJP2 | c.1271C>A p.S424Y | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- TNRC6A | c.3427G>A p.E1143K | Missense Mutation (SNP) | VAF 30/354 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); called by muse, mutect2
- TTN | c.45807G>C p.L15269F (on ENST00000591111; = p.L7845F on NM_003319.4) | Missense Mutation (SNP) | VAF 46/472 reads (10%) | PolyPhen probably damaging (0.984); called by muse, mutect2
- VDAC1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, varscan2
- ZER1 | c.1737+1G>A p.X579_splice | Splice Site (SNP) | VAF 30/149 reads (20%) | called by muse, varscan2
- ZFYVE26 | c.2997G>C p.L999F | Missense Mutation (SNP) | VAF 74/549 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF229 | c.1410C>G p.F470L | Missense Mutation (SNP) | VAF 34/644 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2
- ZNF320 | c.1051C>T p.H351Y | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2
- ZNF35 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- ZNF551 | c.409A>T p.S137C | Missense Mutation (SNP) | VAF 30/477 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF574 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- AEBP2 | c.312C>T p.F104= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as rs1372348426; called by muse, mutect2, varscan2
- ANKDD1B | c.1179C>T p.Y393= | Silent (SNP) | VAF 41/277 reads (15%) | catalogued as rs1249267737, COSV101552586; called by muse, mutect2, varscan2
- ARFIP2 | c.999G>A p.E333= | Silent (SNP) | VAF 18/118 reads (15%) | called by muse, mutect2, varscan2
- ARFRP1 | c.492G>T p.L164= | Silent (SNP) | VAF 34/302 reads (11%) | called by muse, mutect2
- ATAD2 | c.117C>G p.L39= | Silent (SNP) | VAF 34/485 reads (7%) | catalogued as COSV54877507; called by muse, mutect2
- BCL11B | c.1353C>T p.G451= (on ENST00000357195 / NM_001282237.2; = p.G380= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as rs199584715; called by muse, mutect2, varscan2
- CAMK1D | c.777G>C p.L259= | Silent (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- CARMIL1 | c.2019G>A p.E673= | Silent (SNP) | VAF 21/427 reads (5%) | catalogued as rs1448030617; called by muse, mutect2
- CBL | c.729C>A p.I243= | Silent (SNP) | VAF 68/420 reads (16%) | called by muse, mutect2, varscan2
- CBX8 | c.600C>T p.G200= | Silent (SNP) | VAF 37/206 reads (18%) | catalogued as rs757296700; called by muse, mutect2, varscan2
- CNOT1 | c.1785C>G p.L595= | Silent (SNP) | VAF 16/256 reads (6%) | called by muse, mutect2
- DMRTA1 | c.927C>G p.V309= | Silent (SNP) | VAF 78/342 reads (23%) | called by muse, mutect2, varscan2
- DNAH8 | c.11109C>T p.I3703= | Silent (SNP) | VAF 41/257 reads (16%) | catalogued as COSV100547447; called by muse, mutect2, varscan2
- DOCK5 | c.4461C>T p.T1487= | Silent (SNP) | VAF 35/244 reads (14%) | called by muse, mutect2, varscan2
- DPH2 | c.1419G>A p.V473= | Silent (SNP) | VAF 32/221 reads (14%) | called by muse, mutect2, varscan2
- FAM171A1 | c.1599C>T p.D533= | Silent (SNP) | VAF 33/146 reads (23%) | called by muse, mutect2, varscan2
- FAM171B | c.1707C>G p.V569= | Silent (SNP) | VAF 33/252 reads (13%) | catalogued as rs141510558; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.550C>T p.L184= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as rs1557448374; called by muse, mutect2, varscan2
- GRIA1 | c.147C>T p.L49= | Silent (SNP) | VAF 50/391 reads (13%) | called by muse, mutect2, varscan2
- GRIK3 | c.1254G>A p.E418= | Silent (SNP) | VAF 28/156 reads (18%) | called by muse, mutect2, varscan2
- HBA2 | c.345C>T p.P115= | Silent (SNP) | VAF 79/537 reads (15%) | catalogued as CD066366, COSV52406697; called by muse, mutect2, varscan2
- HSPA8 | c.591C>T p.I197= | Silent (SNP) | VAF 25/181 reads (14%) | catalogued as COSV57083664; called by muse, mutect2, varscan2
- ICAM1 | c.1323C>T p.I441= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs760839324; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNH4 | c.1458G>T p.S486= | Silent (SNP) | VAF 23/184 reads (13%) | called by muse, mutect2, varscan2
- LSR | c.1620G>C p.S540= (on ENST00000361790; = p.S521= on NM_015925.6) | Silent (SNP) | VAF 25/877 reads (3%) | called by muse, mutect2
- MARCHF6 | c.2241G>C p.L747= | Silent (SNP) | VAF 91/546 reads (17%) | catalogued as COSV99930080; called by muse, mutect2, varscan2
- MED13 | c.3102C>T p.V1034= | Silent (SNP) | VAF 36/270 reads (13%) | called by muse, mutect2, varscan2
- MINK1 | c.3852C>G p.L1284= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs772442734; called by muse, varscan2
- MRPL14 | c.18G>T p.G6= | Silent (SNP) | VAF 38/357 reads (11%) | called by muse, mutect2, varscan2
- MYLK | c.2217C>A p.L739= | Silent (SNP) | VAF 41/217 reads (19%) | called by muse, mutect2, varscan2
- P2RX2 | c.687C>T p.H229= (on ENST00000343948 / NM_170683.4; = p.H157= on NM_012226.5) | Silent (SNP) | VAF 34/200 reads (17%) | catalogued as rs754679844; called by muse, mutect2, varscan2
- PAX1 | c.96G>A p.A32= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs1302813262; called by muse, mutect2
- PLPBP | c.429C>A p.V143= | Silent (SNP) | VAF 27/207 reads (13%) | called by muse, mutect2, varscan2
- PRX | c.4350G>A p.P1450= | Silent (SNP) | VAF 23/159 reads (14%) | catalogued as rs768051108; called by muse, mutect2, varscan2
- PSMB6 | c.384G>A p.L128= | Silent (SNP) | VAF 35/243 reads (14%) | called by muse, mutect2, varscan2
- RAB19 | c.36G>A p.E12= | Silent (SNP) | VAF 44/198 reads (22%) | called by muse, mutect2, varscan2
- RHBDF1 | c.1935C>G p.L645= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- RPS6KA6 | c.1926C>T p.F642= | Silent (SNP) | VAF 12/163 reads (7%) | catalogued as COSV53117780, COSV53118116; called by muse, mutect2
- RRS1 | c.654G>A p.L218= | Silent (SNP) | VAF 132/255 reads (52%) | called by muse, mutect2, varscan2
- SKIDA1 | c.138C>T p.H46= | Silent (SNP) | VAF 22/285 reads (8%) | called by muse, mutect2
- SLC16A9 | c.285G>A p.L95= | Silent (SNP) | VAF 28/246 reads (11%) | called by muse, mutect2, varscan2
- SLC6A16 | c.306C>A p.A102= | Silent (SNP) | VAF 43/230 reads (19%) | called by muse, mutect2, varscan2
- SLITRK3 | c.2604G>C p.G868= | Silent (SNP) | VAF 12/115 reads (10%) | called by muse, mutect2
- TOPAZ1 | c.2769A>G p.E923= | Silent (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- TRIM23 | c.999A>G p.S333= | Silent (SNP) | VAF 61/362 reads (17%) | called by muse, mutect2, varscan2
- TRIM65 | c.69G>A p.V23= | Silent (SNP) | VAF 43/262 reads (16%) | called by muse, mutect2, varscan2
- TRMT61B | c.216G>C p.L72= | Silent (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- URB1 | c.5994G>A p.L1998= | Silent (SNP) | VAF 25/122 reads (20%) | called by muse, mutect2, varscan2
- UTP20 | c.2604G>C p.R868= | Silent (SNP) | VAF 74/436 reads (17%) | called by muse, mutect2, varscan2
- ZFHX4 | c.624T>C p.D208= | Silent (SNP) | VAF 78/567 reads (14%) | called by muse, mutect2, varscan2
- ZFYVE28 | c.1341C>T p.I447= | Silent (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2
- ZNF646 | c.2949G>A p.G983= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs373982672; called by muse, mutect2, varscan2
- AC018638.4 | n.358C>T | RNA (SNP) | VAF 231/703 reads (33%) | called by muse, mutect2, varscan2
- AGBL3 | c.-15C>G | 5'UTR (SNP) | VAF 20/252 reads (8%) | catalogued as COSV99310432; called by muse, mutect2
- AP003062.1 | n.937T>C | RNA (SNP) | VAF 56/282 reads (20%) | catalogued as rs1396586529; called by muse, varscan2
- ASPM | c.*50A>G | 3'UTR (SNP) | VAF 13/136 reads (10%) | catalogued as rs554369669; called by muse, mutect2
- CEP295 | chr11:93735132 C>G | 3'Flank (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- CIRBP | chr19:1268280 G>T | 5'Flank (SNP) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- DHX30 | c.125-2211C>A | Intron (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- DST | c.20247+69T>A | Intron (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- FAM181A | c.-35C>A | 5'UTR (SNP) | VAF 108/167 reads (65%) | called by muse, mutect2, varscan2
- GABPB1 | c.-1+568C>G | Intron (SNP) | VAF 26/204 reads (13%) | called by muse, mutect2, varscan2
- GLYR1 | c.155+1434_155+1441del | Intron (DEL) | VAF 24/220 reads (11%) | called by mutect2, pindel
- GUSBP10 | n.169G>A | RNA (SNP) | VAF 12/62 reads (19%) | catalogued as rs1248381944; called by muse, mutect2, varscan2
- KCNAB1 | c.276-129664G>A | Intron (SNP) | VAF 73/337 reads (22%) | called by muse, mutect2, varscan2
- LTBP3 | c.*19C>T | 3'UTR (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- MASP1 | c.1091-47G>T | Intron (SNP) | VAF 34/214 reads (16%) | called by muse, mutect2, varscan2
- MKI67 | c.-18C>G | 5'UTR (SNP) | VAF 51/305 reads (17%) | called by muse, mutect2, varscan2
- MMADHC | c.9+16C>T | Intron (SNP) | VAF 68/371 reads (18%) | catalogued as rs774042094; called by muse, mutect2, varscan2
- MPV17 | c.71-33G>C | Intron (SNP) | VAF 42/218 reads (19%) | catalogued as rs1445492059; called by muse, mutect2, varscan2
- MTR | c.*41C>G | 3'UTR (SNP) | VAF 14/274 reads (5%) | called by muse, mutect2
- OPRM1 | c.1165-11127G>C | Intron (SNP) | VAF 9/208 reads (4%) | catalogued as COSV100386502; called by muse, mutect2
- PAQR5 | c.513-48G>A | Intron (SNP) | VAF 18/137 reads (13%) | catalogued as rs1264253481; called by muse, mutect2, varscan2
- PHF2 | c.*1606G>C | 3'UTR (SNP) | VAF 43/223 reads (19%) | called by muse, mutect2, varscan2
- PRND | chr20:4732519 G>T | 3'Flank (SNP) | VAF 51/471 reads (11%) | called by muse, mutect2, varscan2
- RAD51C | c.-1G>T | 5'UTR (SNP) | VAF 48/437 reads (11%) | catalogued as rs750045091; called by muse, mutect2, varscan2
- SPATA31C1 | n.3472G>C | RNA (SNP) | VAF 51/268 reads (19%) | called by muse, mutect2, varscan2
- TBC1D12 | c.-3C>T | 5'UTR (SNP) | VAF 29/87 reads (33%) | catalogued as rs776687705, COSV56552223; called by muse, mutect2, varscan2
- YPEL2 | c.117+127C>T | Intron (SNP) | VAF 23/138 reads (17%) | catalogued as rs754283120; called by muse, mutect2, varscan2
- ZBTB37 | chr1:173864160 del T | 5'Flank (DEL) | VAF 10/106 reads (9%) | called by pindel, varscan2
- ZNF662 | c.-94+175A>C | Intron (SNP) | VAF 43/124 reads (35%) | called by muse, mutect2, varscan2
